Gene-level copy-number profile of tumor specimen TCGA-85-8664-01A from TCGA case TCGA-85-8664, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.8 years (26,954 days).
Specimen TCGA-85-8664-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.c0de6094-7fa9-4f33-8c8b-5c411c50ff0b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8664-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f1030253-1adb-4830-bfd5-7c3246642953

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 286; copy number 2: 18,602; copy number 3: 13,892; copy number 4: 12,233; copy number 5: 9,392; copy number 6: 2,267; copy number 7: 563; copy number 8: 1,623; copy number 9: 254; copy number 10: 142; copy number 11: 387; copy number 12: 17; copy number 13: 56; copy number 14: 8; copy number 15: 1; copy number 22: 5; copy number 29: 43.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8664-01A-11D-2391-01): tumor purity 0.65, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:3,409,133–3,700,628, 2 genes: AC026991.2, RNA5SP251.
- chr10:87,386,685–88,259,372, 21 genes: CTSLP1, FAM245A, AL355334.1, AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1.
- chr16:89,818,179–90,222,851, 22 genes: SPIRE2, TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1, AFG3L1P, DBNDD1, GAS8, GAS8-AS1, URAHP, PRDM7, TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14,758 genes in 53 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–217,137,755, 1,868 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:6,258,348–92,035,000, 1,557 genes, copy number 5–9 (broad region; genes not listed).
- chr2:103,855,829–108,687,246, 95 genes, copy number 6–14 (within-gene range 3–14) (broad region; genes not listed).
- chr3:82,806,515–117,139,389, 371 genes, copy number 5–22 (within-gene range 3–22) (broad region; genes not listed).
- chr3:117,544,205–198,222,513, 1,478 genes, copy number 5–9 (broad region; genes not listed).
- chr5:58,198–53,326,565, 751 genes, copy number 5–15 (broad region; genes not listed).
- chr5:54,286,194–54,872,551, 9 genes, copy number 5: AC008873.1, LINC01033, RPL37P25, HSPB3, SNX18, AC016583.1, AC016583.2, CSPG4BP, AC112198.1.
- chr6:1,079,929–1,613,897, 12 genes, copy number 7: AL033381.1, AL033381.3, FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1.
- chr6:72,316,599–94,194,658, 297 genes, copy number 5–6 (broad region; genes not listed).
- chr7:70,972–11,832,198, 230 genes, copy number 5 (within-gene range 4–10) (broad region; genes not listed).
- chr7:23,891,704–62,275,678, 694 genes, copy number 5–10 (broad region; genes not listed).
- chr7:136,485,656–137,354,483, 11 genes, copy number 5: ZP3P2, AC009264.1, PSMC1P3, CHRM2, MIR490, KRT8P51, AC009517.1, PTN, SNORD81, AC078842.2, AC078842.1.
- chr8:150,584–1,708,476, 28 genes, copy number 5 (within-gene range 2–5): AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4.
- chr8:1,755,778–2,035,587, 14 genes, copy number 5: CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1.
- chr8:4,317,388–6,257,537, 19 genes, copy number 6 (within-gene range 2–6): AC027251.1, AC010941.1, AC022068.1, PAICSP4, AC019176.1, AC019176.2, SNORA70, RN7SL318P, AC007718.1, AC091193.1, RPL23AP54, AC004944.1, AC084768.1, AC084768.2, AC087369.1, AC087369.2, RN7SKP159, AC079054.1, AC009435.1.
- chr8:35,080,592–85,977,154, 797 genes, copy number 5–11 (broad region; genes not listed).
- chr8:87,540,835–117,540,262, 423 genes, copy number 5 (broad region; genes not listed).
- chr8:118,189,455–123,667,248, 85 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr8:124,450,820–137,698,467, 168 genes, copy number 5–12 (broad region; genes not listed).
- chr11:15,701,265–16,739,591, 6 genes, copy number 5 (within-gene range 4–5): AC087379.1, AC009869.1, LINC02682, SOX6, MIR6073, AC103794.1.
- chr11:50,409,042–55,492,148, 29 genes, copy number 7: AC024405.1, OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P, TRIM48, AP005597.4, AP005597.3, AP005597.2, TRIM51HP, AP005597.1, OR4A11P, OR4A12P, OR4A16, OR4A15, OR4A9P, OR4X7P, OR4A10P, OR4A17P, OR4A13P, OR4A50P, OR4A21P.
- chr11:58,905,398–59,058,659, 6 genes, copy number 9 (within-gene range 4–13): GLYATL1, AP001652.1, AP001636.3, AP001636.2, GLYATL1P1, AP001636.1.
- chr11:64,103,188–70,436,584, 345 genes, copy number 6–29 (broad region; genes not listed).
- chr12:66,767–38,589,812, 864 genes, copy number 5–8 (broad region; genes not listed).
- chr12:58,244,378–58,395,138, 2 genes, copy number 6: RPL21P103, AC025578.1.
- chr12:66,950,754–70,920,738, 86 genes, copy number 6 (broad region; genes not listed).
- chr12:85,781,892–92,772,455, 87 genes, copy number 5 (broad region; genes not listed).
- chr15:19,878,555–101,933,350, 2,215 genes, copy number 5 (within-gene range 5–12) (broad region; genes not listed).
- chr18:20,946,906–46,072,272, 328 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).
- chr18:51,346,249–71,237,158, 265 genes, copy number 5–6 (broad region; genes not listed).
- chr19:27,638,483–27,794,005, 3 genes, copy number 9 (within-gene range 4–9): ERVK-28, AC112702.1, LINC00662.
- chr19:35,124,513–45,873,797, 585 genes, copy number 6–11 (broad region; genes not listed).
- chr20:87,250–16,053,197, 291 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr20:15,280,764–37,406,050, 502 genes, copy number 6–8 (broad region; genes not listed).
- chr20:38,260,149–38,578,859, 22 genes, copy number 10 (within-gene range 4–10): AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2.
- chr20:38,977,711–44,069,616, 67 genes, copy number 5–14 (within-gene range 4–14) (broad region; genes not listed).
- chr20:45,833,799–47,493,085, 52 genes, copy number 13: SNX21, ACOT8, Metazoa_SRP, ZSWIM3, ZSWIM1, SPATA25, NEURL2, CTSA, AL008726.1, PLTP, AL162458.1, PCIF1, ZNF335, FTLP1, MMP9, SLC12A5-AS1, SLC12A5, NCOA5, RPL13P2, CD40, AL031687.1, CDH22, SLC35C2, AL133227.1, ELMO2, ZNF663P, AL031686.1, MKRN7P, ZNF840P, ZNF334, OCSTAMP, SLC13A3, AL133520.1, TP53RK, AL031055.1, SLC2A10, RN7SKP33, AL354766.1, EYA2, AL354766.2, GAPDHP54, AL121776.1, AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P.
- chr20:50,247,643–51,131,667, 26 genes, copy number 8–12: PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645, RIPOR3, MIR1302-5, RPL36P2, RIPOR3-AS1, PARD6B, BCAS4, TMSB4XP6, ADNP, PSMD10P1, ADNP-AS1, DPM1, MOCS3, AL050404.1, KCNG1, AL121785.1, RPSAP1.
- chr20:54,859,688–57,525,652, 50 genes, copy number 5–10: RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1, AL109829.1, AL109828.1, CBLN4, RNA5SP487, MC3R, AL139824.2, AL139824.1, FAM210B, AURKA, CSTF1, CASS4, RPL39P, RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, AL109806.2, LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P, AL157414.2, AL157414.1, AL157414.4, AL157414.3, BMP7, BMP7-AS1, AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, AL109955.1, HMGB1P1, CTCFL.
- chr20:64,255,695–64,313,132, 4 genes, copy number 7: PCMTD2, AL137028.2, CICP4, LINC00266-1.

Autosomal genes at a single copy (total copy number 1): 278. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
